Somatic mutation profile of tumor specimen C3N-01620-03 (aliquot CPT0095040008) from CPTAC case C3N-01620, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 56.9 years (20,774 days).
Specimen C3N-01620-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6fa67b26-3dac-40eb-a882-886d447d1f9d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01620-31 (Blood Derived Normal), aliquot CPT0095090002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e535d49f-142b-4668-82c9-f85a0e6d4222

The open-access MAF lists 200 somatic variants for this specimen: 129 protein-altering or splice-affecting, 49 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 106, Silent 49, Intron 12, Nonsense Mutation 9, Frame Shift Del 4, Splice Region 4, 3'UTR 4, Splice Site 3, RNA 2, Frame Shift Ins 2, 5'UTR 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYO15A | c.3866+1G>A p.X1289_splice | Splice Site (SNP) | VAF 38/206 reads (18%) | catalogued as rs374742590, CS075187; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.10774G>A p.V3592M | Missense Mutation (SNP) | VAF 66/211 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs568929494; called by muse, mutect2, varscan2
- AC097637.1 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 13/169 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs778298315; called by muse, mutect2
- ACTN1 | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 26/157 reads (17%) | catalogued as rs149484448; called by muse, mutect2, varscan2
- ADCY1 | c.3142G>T p.E1048* | Nonsense Mutation (SNP) | VAF 25/419 reads (6%) | catalogued as COSV104397707; called by muse, mutect2
- ANKRD7 | c.208G>A p.G70R | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs770762529, COSV54555755; called by muse, mutect2, varscan2
- ARL6IP4 | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 14/183 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.526); catalogued as rs1179493491, COSV54900320; called by muse, mutect2
- BROX | c.1048C>T p.L350F | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs375941347; called by muse, mutect2, varscan2
- CAPN3 | c.1928G>A p.S643N | Missense Mutation (SNP) | VAF 46/368 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs142391359; called by muse, varscan2
- COL6A5 | c.4432C>T p.H1478Y | Missense Mutation (SNP) | VAF 10/260 reads (4%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs906919907; called by muse, mutect2
- CYLD | c.2554G>A p.G852S | Missense Mutation (SNP) | VAF 44/479 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as rs1285455482, COSV61095089, COSV61097062; called by muse, mutect2
- DMD | c.10036G>A p.V3346I | Missense Mutation (SNP) | VAF 105/300 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.03); catalogued as rs774061155; called by muse, mutect2, varscan2
- DNAH11 | c.11098G>T p.E3700* | Nonsense Mutation (SNP) | VAF 47/540 reads (9%) | catalogued as COSV60967492; called by muse, mutect2
- DRD4 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 67/379 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs1218964221; called by muse, mutect2, varscan2
- EFCAB13 | c.754C>A p.P252T | Missense Mutation (SNP) | VAF 25/268 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as COSV58946968; called by muse, mutect2
- ERC2 | c.988C>T p.R330W | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as rs551910401, COSV55637118; called by muse, mutect2, varscan2
- EWSR1 | c.1234G>A p.D412N | Missense Mutation (SNP) | VAF 26/212 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.468); catalogued as rs755735886, COSV58426183; called by muse, mutect2, varscan2
- FLG | c.4645C>T p.Q1549* | Nonsense Mutation (SNP) | VAF 67/474 reads (14%) | catalogued as COSV64252606; called by muse, mutect2, varscan2
- FLNC | c.5281G>A p.A1761T | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs376023896; ClinVar: uncertain significance; called by muse, mutect2
- FOXD4L5 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 36/970 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV101073109; called by muse, mutect2
- FSTL5 | c.1650C>G p.D550E | Missense Mutation (SNP) | VAF 44/212 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.757); catalogued as rs1284756527, COSV60217659; called by muse, varscan2
- GABRB3 | c.288G>C p.R96S | Missense Mutation (SNP) | VAF 23/243 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100159894; called by muse, mutect2
- H1-4 | c.511A>G p.K171E | Missense Mutation (SNP) | VAF 40/448 reads (9%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.968); catalogued as rs1484879109; called by muse, mutect2
- HEPACAM2 | c.1364C>T p.A455V (on ENST00000394468 / NM_001039372.4; = p.A443V on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/222 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.056); catalogued as rs764959717, COSV59061548; called by muse, mutect2, varscan2
- HIVEP1 | c.2033G>A p.R678H | Missense Mutation (SNP) | VAF 34/413 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs192064941, COSV65105388; called by muse, mutect2
- HOXA2 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1043147767; called by muse, mutect2
- IARS1 | c.1555C>T p.R519C | Missense Mutation (SNP) | VAF 50/227 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754905369; called by muse, mutect2, varscan2
- LRP1B | c.12544G>A p.E4182K | Missense Mutation (SNP) | VAF 27/211 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as rs201840295, COSV101254959; called by muse, mutect2, varscan2
- MESP2 | c.218G>C p.R73P | Missense Mutation (SNP) | VAF 19/308 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs771745973; ClinVar: uncertain significance; called by muse, mutect2
- MINK1 | c.582G>C p.W194C | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100767312; called by muse, mutect2
- MUC4 | c.3649C>G p.L1217V | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.374); catalogued as COSV62137424; called by muse, varscan2
- NBEA | c.1627G>C p.E543Q | Missense Mutation (SNP) | VAF 36/222 reads (16%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.968); catalogued as COSV59803216; called by muse, mutect2, varscan2
- NBPF1 | c.2213A>G p.E738G | Missense Mutation (SNP) | VAF 88/1071 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.746); catalogued as rs759337305; called by muse, mutect2
- NOD2 | c.1190C>T p.P397L | Missense Mutation (SNP) | VAF 72/858 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150078153; ClinVar: uncertain significance / benign; called by muse, mutect2
- OR1D2 | c.618C>G p.I206M | Missense Mutation (SNP) | VAF 31/346 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.611); catalogued as rs767228355; called by muse, mutect2
- OR4C3 | c.485T>G p.L162R | Missense Mutation (SNP) | VAF 9/170 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV60583417; called by muse, mutect2
- OR5T2 | c.686C>A p.S229Y | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100506828; called by muse, mutect2, varscan2
- PCDH18 | c.3056C>A p.S1019Y | Missense Mutation (SNP) | VAF 27/209 reads (13%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.656); catalogued as COSV61269902; called by muse, mutect2, varscan2
- PLEKHA7 | c.2680C>T p.H894Y | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.435); catalogued as rs1483929196; called by muse, mutect2
- RLBP1 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 64/369 reads (17%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.583); catalogued as rs1195086138; called by muse, mutect2, varscan2
- RYR2 | c.3866C>A p.S1289Y | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV104419098; called by muse, varscan2
- SLC49A4 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 24/193 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs371361425; called by muse, mutect2, varscan2
- TBCD | c.3565-5_3565-3del | Splice Region (DEL) | VAF 42/298 reads (14%) | catalogued as rs755792122; called by pindel, varscan2
- TGFB1I1 | c.68C>T p.A23V (on ENST00000394863 / NM_001042454.3; = p.A6V on NM_015927.4) | Missense Mutation (SNP) | VAF 43/262 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as rs1484965766, COSV62357885; called by muse, mutect2, varscan2
- TMEM132C | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 64/448 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV70673401; called by muse, mutect2, varscan2
- TMEM63B | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.025); catalogued as rs375760449; called by muse, mutect2, varscan2
- TMEM63C | c.1322G>A p.R441H | Missense Mutation (SNP) | VAF 41/228 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.236); catalogued as rs763288885; called by muse, mutect2, varscan2
- TPRN | c.1712C>T p.S571F | Missense Mutation (SNP) | VAF 36/257 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs140967677; called by muse, mutect2, varscan2
- TTN | c.86166G>C p.K28722N (on ENST00000591111; = p.K21298N on NM_003319.4) | Missense Mutation (SNP) | VAF 21/246 reads (9%) | PolyPhen probably damaging (0.997); catalogued as COSV60323926, COSV60339610; called by muse, mutect2
- UTP20 | c.4599G>C p.Q1533H | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as rs754118365; called by muse, mutect2, varscan2
- WDR89 | c.1019_1021del p.G340del | In Frame Del (DEL) | VAF 24/194 reads (12%) | catalogued as rs1444279086; called by pindel, varscan2
- WNK4 | c.2111G>A p.R704Q | Missense Mutation (SNP) | VAF 66/405 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as rs150554297; called by muse, mutect2, varscan2
- ZNF549 | c.1562G>T p.R521I (on ENST00000376233 / NM_001199295.2; = p.R508I on NM_153263.2) | Missense Mutation (SNP) | VAF 46/238 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs1175943930, COSV99558454; called by muse, mutect2, varscan2
- ANOS1 | c.1603G>A p.G535S | Missense Mutation (SNP) | VAF 13/198 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ASL | c.1357C>A p.R453S | Missense Mutation (SNP) | VAF 97/504 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- BMPER | c.838C>T p.Q280* | Nonsense Mutation (SNP) | VAF 68/682 reads (10%) | called by muse, mutect2, varscan2
- CARMIL3 | c.612G>T p.L204F | Missense Mutation (SNP) | VAF 48/294 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CAVIN4 | c.283A>G p.K95E | Missense Mutation (SNP) | VAF 21/276 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CCDC15 | c.1062G>C p.Q354H | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.018); called by muse, mutect2
- CCDC91 | c.305A>T p.E102V | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDC42BPG | c.712A>G p.I238V | Missense Mutation (SNP) | VAF 83/453 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CDK14 | c.211G>A p.V71I (on ENST00000380050 / NM_001287135.2; = p.V53I on NM_012395.3) | Missense Mutation (SNP) | VAF 40/366 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CLDN11 | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 23/444 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2
- CSN1S1 | c.306G>C p.Q102H | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- CYP2C19 | c.1279C>A p.P427T | Missense Mutation (SNP) | VAF 40/213 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- DHRS12 | c.181G>A p.A61T (on ENST00000444610 / NM_001377930.1; = p.S39= on NM_024705.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DIDO1 | c.2613dup p.Q872Tfs*8 | Frame Shift Ins (INS) | VAF 35/162 reads (22%) | called by mutect2, pindel, varscan2
- DNAH17 | c.6777del p.G2260Afs*16 | Frame Shift Del (DEL) | VAF 22/108 reads (20%) | called by mutect2, pindel, varscan2
- DNAH7 | c.10986C>A p.F3662L | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- DNAJB11 | c.332G>C p.G111A | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, varscan2
- ECSIT | c.241G>T p.G81C | Missense Mutation (SNP) | VAF 46/296 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- EIF4A3 | c.696C>A p.F232L | Missense Mutation (SNP) | VAF 30/181 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- ENPP2 | c.1412dup p.Q472Pfs*7 (on ENST00000075322 / NM_001040092.3; = p.Q524Pfs*7 on NM_006209.5) | Frame Shift Ins (INS) | VAF 39/247 reads (16%) | called by mutect2, pindel, varscan2
- ERCC6L2 | c.3787T>C p.Y1263H | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- FAM83B | c.689A>C p.K230T | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- FBXL12 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 17/210 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.206); called by muse, mutect2
- FOXB2 | c.1000G>A p.G334R | Missense Mutation (SNP) | VAF 21/236 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.744); called by muse, mutect2
- GLI4 | c.224-1G>A p.X75_splice | Splice Site (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2
- GLT1D1 | c.659G>A p.R220K (on ENST00000442111 / NM_001366889.1; = p.R140K on NM_144669.3) | Missense Mutation (SNP) | VAF 38/255 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- GRIK1 | c.1720C>G p.L574V | Missense Mutation (SNP) | VAF 47/250 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- HLX | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 34/184 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HSPB1 | c.556G>C p.E186Q | Missense Mutation (SNP) | VAF 44/630 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.046); called by muse, mutect2
- IDI1 | c.314-3C>G | Splice Region (SNP) | VAF 10/112 reads (9%) | called by muse, mutect2
- IGKV1D-8 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 55/320 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- KCNIP4 | c.456G>T p.L152F | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KRT5 | c.956_957del p.S319* | Frame Shift Del (DEL) | VAF 87/662 reads (13%) | called by pindel, varscan2
- LDHA | c.502G>T p.A168S | Missense Mutation (SNP) | VAF 47/300 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- MED13L | c.2470-8G>T | Splice Region (SNP) | VAF 67/396 reads (17%) | called by muse, mutect2, varscan2
- MFSD3 | c.686A>C p.E229A | Missense Mutation (SNP) | VAF 15/162 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- MSH6 | c.877C>G p.P293A | Missense Mutation (SNP) | VAF 40/447 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2
- MYO10 | c.3037C>T p.H1013Y | Missense Mutation (SNP) | VAF 11/222 reads (5%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.369); called by muse, mutect2
- NDN | c.72C>A p.S24R | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); called by muse, mutect2
- NIBAN1 | c.2752C>T p.Q918* | Nonsense Mutation (SNP) | VAF 47/296 reads (16%) | called by muse, mutect2, varscan2
- NMRAL1 | c.559G>A p.G187S | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NSD1 | c.6880G>A p.D2294N | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.101); called by muse, mutect2
- NXNL1 | c.159C>G p.I53M | Missense Mutation (SNP) | VAF 34/424 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.072); called by muse, mutect2
- PCDHB11 | c.1660G>A p.A554T | Missense Mutation (SNP) | VAF 114/810 reads (14%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- PCDHB7 | c.1935G>C p.K645N | Missense Mutation (SNP) | VAF 74/1822 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.892); called by muse, mutect2
- PIEZO1 | c.3348C>G p.F1116L | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PLXNB2 | c.2402C>T p.P801L | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POTEE | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 14/304 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.088); called by muse, mutect2
- PRDM14 | c.1410C>A p.F470L | Missense Mutation (SNP) | VAF 32/233 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, varscan2
- RACGAP1 | c.1663G>A p.V555I | Missense Mutation (SNP) | VAF 43/304 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- RFX2 | c.1760G>A p.W587* | Nonsense Mutation (SNP) | VAF 20/155 reads (13%) | called by muse, mutect2, varscan2
- RFXAP | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RGMB | c.1215G>A p.W405* (on ENST00000513185 / NM_001366508.1; = p.W446* on NM_001012761.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 50/315 reads (16%) | called by muse, mutect2, varscan2
- RIOX2 | c.165C>G p.F55L | Missense Mutation (SNP) | VAF 22/398 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.705); called by muse, mutect2
- RNF123 | c.3739-3C>A | Splice Region (SNP) | VAF 26/123 reads (21%) | called by muse, mutect2, varscan2
- ROBO4 | c.1420T>G p.C474G | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- RP1 | c.1856A>C p.N619T | Missense Mutation (SNP) | VAF 98/683 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- RPE65 | c.248T>C p.F83S | Missense Mutation (SNP) | VAF 41/478 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- SCAF8 | c.976C>G p.Q326E | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.073); called by muse, mutect2
- SLC1A4 | c.1090_1115del p.K364Hfs*72 | Frame Shift Del (DEL) | VAF 21/222 reads (9%) | called by mutect2, pindel
- SLIT2 | c.421G>C p.A141P | Missense Mutation (SNP) | VAF 12/295 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); called by muse, mutect2
- SNX31 | c.1223_1227+11delinsAAGCCAGGTCTGTGAAATGTC p.X408_splice | Splice Site (INS) | VAF 15/187 reads (8%) | called by pindel, varscan2*
- SRSF11 | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- ST6GAL2 | c.440C>T p.T147I | Missense Mutation (SNP) | VAF 17/171 reads (10%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- STARD3NL | c.134del p.K45Rfs*22 | Frame Shift Del (DEL) | VAF 175/633 reads (28%) | called by mutect2, pindel, varscan2
- STRADA | c.284A>G p.E95G (on ENST00000336174 / NM_001363786.1; = p.E58G on NM_153335.6) | Missense Mutation (SNP) | VAF 52/335 reads (16%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.911); called by muse, varscan2
- TFG | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 47/245 reads (19%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TMEM181 | c.743G>T p.G248V | Missense Mutation (SNP) | VAF 28/310 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.596); called by muse, mutect2
- TPBG | c.1064C>G p.S355C | Missense Mutation (SNP) | VAF 15/149 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRGC2 | c.153C>A p.S51R | Missense Mutation (SNP) | VAF 31/423 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.189); called by muse, mutect2
- UBASH3B | c.1065G>T p.Q355H | Missense Mutation (SNP) | VAF 36/252 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- UGGT2 | c.616G>T p.A206S | Missense Mutation (SNP) | VAF 24/198 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- USP9X | c.5275A>T p.K1759* | Nonsense Mutation (SNP) | VAF 37/122 reads (30%) | called by muse, mutect2, varscan2
- WDFY1 | c.577A>T p.T193S | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.033); called by muse, mutect2
- ZFYVE16 | c.2681G>T p.R894I | Missense Mutation (SNP) | VAF 30/201 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- ZNF729 | c.3585A>T p.K1195N | Missense Mutation (SNP) | VAF 57/409 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- ABCA5 | c.3804C>T p.V1268= | Silent (SNP) | VAF 30/229 reads (13%) | called by muse, mutect2, varscan2
- AHCYL2 | c.690G>A p.V230= | Silent (SNP) | VAF 23/199 reads (12%) | called by muse, mutect2, varscan2
- ANKRD11 | c.6594G>T p.R2198= | Silent (SNP) | VAF 14/151 reads (9%) | catalogued as COSV56355474; called by muse, mutect2
- ARFGEF3 | c.4875G>T p.L1625= | Silent (SNP) | VAF 17/85 reads (20%) | called by muse, mutect2, varscan2
- CELSR2 | c.6225G>A p.K2075= | Silent (SNP) | VAF 15/156 reads (10%) | catalogued as rs1381696640; called by muse, mutect2
- CNTD1 | c.183C>G p.L61= | Silent (SNP) | VAF 26/193 reads (13%) | called by muse, mutect2, varscan2
- CPXM2 | c.1386G>T p.L462= | Silent (SNP) | VAF 47/243 reads (19%) | called by muse, mutect2, varscan2
- CR1L | c.645C>T p.G215= | Silent (SNP) | VAF 99/556 reads (18%) | catalogued as rs758723371; called by muse, mutect2, varscan2
- CYP11B1 | c.285G>A p.E95= | Silent (SNP) | VAF 75/500 reads (15%) | called by muse, mutect2, varscan2
- DST | c.19636C>T p.L6546= (on ENST00000361203 / NM_001374722.1; = p.L4243= on NM_015548.5) | Silent (SNP) | VAF 62/432 reads (14%) | catalogued as rs1439679404; called by muse, mutect2, varscan2
- ECPAS | c.3480T>C p.D1160= | Silent (SNP) | VAF 35/232 reads (15%) | called by muse, mutect2, varscan2
- FBF1 | c.3183T>C p.P1061= (on ENST00000586717; = p.P1076= on NM_001319193.1) | Silent (SNP) | VAF 19/126 reads (15%) | called by muse, mutect2, varscan2
- FN1 | c.4542T>C p.Y1514= | Silent (SNP) | VAF 49/247 reads (20%) | called by muse, mutect2, varscan2
- GEMIN4 | c.1363T>C p.L455= | Silent (SNP) | VAF 34/371 reads (9%) | catalogued as rs777855269; called by muse, mutect2
- HELQ | c.2769C>A p.I923= | Silent (SNP) | VAF 38/147 reads (26%) | catalogued as COSV99787873; called by muse, mutect2, varscan2
- HLA-G | c.489G>A p.A163= | Silent (SNP) | VAF 60/555 reads (11%) | called by muse, mutect2, varscan2
- IQSEC3 | c.376C>A p.R126= | Silent (SNP) | VAF 60/455 reads (13%) | catalogued as rs1555065980; called by muse, mutect2, varscan2
- KCNV1 | c.12C>T p.S4= | Silent (SNP) | VAF 17/106 reads (16%) | called by muse, mutect2, varscan2
- METTL24 | c.138G>A p.P46= | Silent (SNP) | VAF 13/55 reads (24%) | called by muse, mutect2, varscan2
- MN1 | c.1155G>A p.E385= | Silent (SNP) | VAF 8/44 reads (18%) | called by muse, mutect2, varscan2
- MUC16 | c.15486T>C p.D5162= | Silent (SNP) | VAF 35/188 reads (19%) | called by muse, mutect2, varscan2
- MYO6 | c.2673G>A p.T891= | Silent (SNP) | VAF 46/308 reads (15%) | catalogued as rs755638459; called by muse, mutect2, varscan2
- NDNF | c.105G>A p.R35= | Silent (SNP) | VAF 63/248 reads (25%) | called by muse, mutect2, varscan2
- NEDD9 | c.2337C>T p.S779= | Silent (SNP) | VAF 34/399 reads (9%) | catalogued as rs1261496669; called by muse, mutect2
- OPRM1 | c.123G>T p.L41= | Silent (SNP) | VAF 27/160 reads (17%) | called by muse, mutect2, varscan2
- OR10G2 | c.120C>A p.I40= | Silent (SNP) | VAF 47/263 reads (18%) | called by muse, mutect2, varscan2
- OR4D9 | c.555C>A p.L185= | Silent (SNP) | VAF 42/330 reads (13%) | called by muse, varscan2
- OR5AC2 | c.114C>A p.L38= | Silent (SNP) | VAF 16/236 reads (7%) | catalogued as COSV62279443; called by muse, mutect2
- P2RY1 | c.426G>C p.L142= | Silent (SNP) | VAF 15/390 reads (4%) | called by muse, mutect2
- PAX1 | c.279C>T p.L93= | Silent (SNP) | VAF 23/91 reads (25%) | called by muse, mutect2, varscan2
- PCDHA5 | c.1683G>C p.A561= | Silent (SNP) | VAF 95/589 reads (16%) | called by muse, mutect2, varscan2
- PDLIM1 | c.390G>T p.S130= | Silent (SNP) | VAF 37/264 reads (14%) | catalogued as COSV100267666; called by muse, mutect2, varscan2
- PRPF6 | c.2775G>A p.K925= | Silent (SNP) | VAF 72/446 reads (16%) | catalogued as COSV53876013; called by muse, mutect2, varscan2
- PUF60 | c.1581G>A p.K527= (on ENST00000526683 / NM_001362896.2; = p.K510= on NM_014281.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 51/407 reads (13%) | called by muse, mutect2, varscan2
- RACGAP1 | c.519G>A p.K173= | Silent (SNP) | VAF 15/146 reads (10%) | called by muse, mutect2, varscan2
- RIOX1 | c.687G>T p.L229= | Silent (SNP) | VAF 22/181 reads (12%) | called by muse, mutect2, varscan2
- SEMA7A | c.1468C>T p.L490= | Silent (SNP) | VAF 20/148 reads (14%) | called by muse, mutect2, varscan2
- SHANK2 | c.2985C>T p.I995= | Silent (SNP) | VAF 93/894 reads (10%) | catalogued as rs570428272, COSV53593703; called by muse, mutect2, varscan2
- TBX10 | c.1113G>C p.L371= | Silent (SNP) | VAF 26/312 reads (8%) | called by muse, mutect2
- TET3 | c.3201G>A p.T1067= | Silent (SNP) | VAF 10/99 reads (10%) | catalogued as rs531982919; called by muse, mutect2, varscan2
- TGM1 | c.1566C>T p.A522= | Silent (SNP) | VAF 96/545 reads (18%) | called by muse, mutect2, varscan2
- TMPRSS11E | c.438G>T p.L146= | Silent (SNP) | VAF 24/183 reads (13%) | catalogued as rs138380711; called by muse, varscan2
- TTC39C | c.1176C>T p.Y392= (on ENST00000317571 / NM_001135993.2; = p.Y331= on NM_153211.4) | Silent (SNP) | VAF 16/128 reads (13%) | called by muse, mutect2, varscan2
- VPS8 | c.67C>T p.L23= | Silent (SNP) | VAF 10/278 reads (4%) | called by muse, mutect2
- VSIG4 | c.600T>C p.P200= | Silent (SNP) | VAF 25/193 reads (13%) | called by muse, mutect2, varscan2
- XIRP2 | c.3510A>C p.G1170= (on ENST00000628543; = p.G1345= on NM_152381.6) | Silent (SNP) | VAF 12/258 reads (5%) | called by muse, mutect2
- ZNF493 | c.1464T>C p.L488= | Silent (SNP) | VAF 18/341 reads (5%) | called by muse, mutect2
- ZNF729 | c.657G>A p.S219= | Silent (SNP) | VAF 23/145 reads (16%) | catalogued as rs766297588; called by muse, mutect2, varscan2
- ZNF804A | c.3048T>A p.T1016= | Silent (SNP) | VAF 42/224 reads (19%) | called by muse, mutect2, varscan2
- ABHD3 | c.555+349C>G | Intron (SNP) | VAF 20/218 reads (9%) | called by muse, mutect2
- AC136604.1 | n.290G>C | RNA (SNP) | VAF 36/321 reads (11%) | called by muse, mutect2, varscan2
- ARIH1 | c.-18del | 5'UTR (DEL) | VAF 15/177 reads (8%) | called by mutect2, pindel
- CCHCR1 | c.-51-88G>A | Intron (SNP) | VAF 30/373 reads (8%) | catalogued as rs1373151849; called by muse, mutect2
- CEP41 | c.*508G>A | 3'UTR (SNP) | VAF 26/244 reads (11%) | called by muse, mutect2, varscan2
- CERS5 | c.1029+1489G>A | Intron (SNP) | VAF 12/161 reads (7%) | called by muse, mutect2
- CHMP5 | c.-8T>A | 5'UTR (SNP) | VAF 56/240 reads (23%) | called by muse, mutect2, varscan2
- EYS | c.1767-8174T>A | Intron (SNP) | VAF 6/36 reads (17%) | called by mutect2, varscan2
- FRMD8P1 | n.708G>C | RNA (SNP) | VAF 27/160 reads (17%) | called by muse, mutect2, varscan2
- GP2 | c.*19G>A | 3'UTR (SNP) | VAF 20/190 reads (11%) | catalogued as rs1486669925; called by muse, mutect2
- GRSF1 | c.357+41_357+42delinsT | Intron (DEL) | VAF 32/229 reads (14%) | called by pindel, varscan2*
- IGFN1 | c.1242-947G>T | Intron (SNP) | VAF 15/211 reads (7%) | called by muse, mutect2
- KIF1B | c.2115+6527C>A | Intron (SNP) | VAF 90/503 reads (18%) | called by muse, mutect2, varscan2
- LENG8 | c.*2419C>A | 3'UTR (SNP) | VAF 13/119 reads (11%) | called by muse, mutect2, varscan2
- LEP | c.*28G>C | 3'UTR (SNP) | VAF 22/342 reads (6%) | called by muse, mutect2
- OARD1 | c.184+44A>T | Intron (SNP) | VAF 61/362 reads (17%) | called by muse, mutect2, varscan2
- PARVB | c.713-99G>T | Intron (SNP) | VAF 16/349 reads (5%) | called by muse, mutect2
- RAB11FIP5 | c.432-35G>A | Intron (SNP) | VAF 49/238 reads (21%) | catalogued as rs764271777, COSV99242072; called by muse, mutect2, varscan2
- RHBDL1 | c.985-27C>G | Intron (SNP) | VAF 14/115 reads (12%) | called by mutect2, varscan2
- RNY4P30 | chr13:49891166 G>T | 5'Flank (SNP) | VAF 31/380 reads (8%) | called by muse, mutect2
- SEC13 | c.165-711del | Intron (DEL) | VAF 15/66 reads (23%) | catalogued as rs758959122; called by mutect2, pindel, varscan2
- SNORA75 | chr12:9288316 C>A | 5'Flank (SNP) | VAF 28/318 reads (9%) | called by muse, mutect2, varscan2
